Somatic mutation profile of tumor specimen MMRF_1178_1_BM_CD138pos (aliquot MMRF_1178_1_BM_CD138pos_T1_KAS5U_L01919) from MMRF case MMRF_1178, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.8 years (22,222 days).
Specimen MMRF_1178_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dfdb6b3-561a-4d8d-9f62-82cdb0900909.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1178_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1178_1_PB_Whole_C2_KAS5U_L01931; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7200b266-0376-45dc-b6b8-846f358a869d

The open-access MAF lists 69 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 20, Silent 8, Intron 7, RNA 3, 3'Flank 3, 5'UTR 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK19 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1362613045; called by muse, mutect2, varscan2
- EML2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1483263409; called by muse, mutect2, varscan2
- GDF3 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 45/87 reads (52%) | catalogued as COSV61712074, COSV61712367; called by muse, mutect2, varscan2
- IGLV3-10 | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.774); catalogued as rs188439978; called by muse, mutect2, varscan2
- PDE10A | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV63094378; called by muse, varscan2
- SEC14L5 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750893044, COSV52037622; called by muse, mutect2, varscan2
- SVEP1 | c.3917C>G p.T1306R | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as rs199822875; called by muse, mutect2, varscan2
- ATR | c.1570T>C p.S524P | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CDK10 | c.500C>A p.S167Y (on ENST00000353379 / NM_052988.5; = p.S96Y on NM_052987.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CMTM5 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CSNK1G2 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH11 | c.7625C>A p.T2542K | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FRYL | c.4321G>C p.E1441Q | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IGHV1-69 | c.216_229del p.I73Kfs*31 | Frame Shift Del (DEL) | VAF 35/98 reads (36%) | called by mutect2, varscan2
- KCTD12 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.37); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- MROH9 | c.304A>T p.I102F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSANTD3-TMEFF1 | c.54A>T p.E18D | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP9 | c.1033A>C p.T345P | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- NRK | c.4042G>A p.E1348K | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.44); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- PDE10A | c.1537A>G p.M513V | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, varscan2
- PLCG2 | c.2983T>G p.S995A | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PNRC1 | c.650A>G p.K217R | Missense Mutation (SNP) | VAF 117/431 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- POLE | c.2212A>G p.K738E | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SARDH | c.398T>C p.V133A | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TASOR2 | c.7029G>C p.L2343F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- UBE3A | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- B3GNT3 | c.231G>A p.P77= | Silent (SNP) | VAF 97/176 reads (55%) | catalogued as rs1041281671; called by muse, mutect2, varscan2
- GPBAR1 | c.184C>T p.L62= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- IGKV4-1 | c.174C>T p.Y58= | Silent (SNP) | VAF 48/53 reads (91%) | catalogued as rs372445127; called by muse, varscan2
- KRTAP26-1 | c.240C>T p.C80= | Silent (SNP) | VAF 51/96 reads (53%) | catalogued as rs751042226; called by muse, mutect2, varscan2
- MYO7A | c.3690C>A p.R1230= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- OR8D1 | c.633C>A p.T211= | Silent (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- OVCH1 | c.990G>A p.K330= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV58959888; called by muse, mutect2, varscan2
- PCDHGA4 | c.1653C>T p.F551= | Silent (SNP) | VAF 92/215 reads (43%) | catalogued as COSV53941730; called by muse, mutect2, varscan2
- AC025538.1 | n.1052G>A | RNA (SNP) | VAF 31/74 reads (42%) | catalogued as rs1374934768; called by muse, mutect2, varscan2
- AC093791.1 | n.646A>G | RNA (SNP) | VAF 120/249 reads (48%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*1732G>A | 3'UTR (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- ANKRD17 | c.*1302C>A | 3'UTR (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- BCLAF1 | c.*1105A>T | 3'UTR (SNP) | VAF 39/157 reads (25%) | called by muse, mutect2, varscan2
- BTG2 | c.*1964_*1966del | 3'UTR (DEL) | VAF 29/109 reads (27%) | called by pindel, varscan2
- C16orf72 | c.*4605G>T | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- C1orf43 | c.*283T>G | 3'UTR (SNP) | VAF 74/120 reads (62%) | called by muse, mutect2, varscan2
- CCNT1 | c.*1126G>T | 3'UTR (SNP) | VAF 58/120 reads (48%) | called by muse, mutect2, varscan2
- CNR1 | c.*1134G>C | 3'UTR (SNP) | VAF 63/217 reads (29%) | called by muse, mutect2, varscan2
- CYYR1 | c.*1465T>C | 3'UTR (SNP) | VAF 41/104 reads (39%) | called by muse, mutect2, varscan2
- DHX30 | c.125-2311C>T | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- DTX1 | c.-433C>T | 5'UTR (SNP) | VAF 14/31 reads (45%) | catalogued as rs546652296, COSV57495151, COSV57497550; called by muse, mutect2
- EPC1 | chr10:32268142 A>T | 3'Flank (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- FAP | c.2107+118A>G | Intron (SNP) | VAF 46/111 reads (41%) | catalogued as rs1050380754; called by muse, mutect2, varscan2
- GOSR2 | chr17:46940744 G>A | 3'Flank (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- LINC01343 | n.442G>A | RNA (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- LTB | c.208+73T>A | Intron (SNP) | VAF 88/147 reads (60%) | called by muse, mutect2, varscan2
- LYPD1 | c.*120G>A | 3'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs1470984349; called by muse, mutect2
- MAU2 | c.*877G>C | 3'UTR (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2
- MCC | c.*4460A>G | 3'UTR (SNP) | VAF 54/141 reads (38%) | called by muse, mutect2, varscan2
- MGAT4A | c.*2616G>T | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- MICAL1 | c.2304+66C>T | Intron (SNP) | VAF 30/92 reads (33%) | catalogued as rs1460032943; called by muse, mutect2, varscan2
- MICALL2 | c.2122+152C>G | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- MTHFR | c.*4685T>G | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- NPR2 | c.-145C>A | 5'UTR (SNP) | VAF 52/178 reads (29%) | called by muse, mutect2, varscan2
- POP1 | chr8:98158481 T>G | 3'Flank (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- PRKDC | c.11108-137C>G | Intron (SNP) | VAF 30/72 reads (42%) | catalogued as COSV58047035; called by muse, varscan2
- STK32A | c.*1782G>C | 3'UTR (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- TATDN3 | c.*1250A>G | 3'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as rs1053859768; called by muse, mutect2, varscan2
- TMEM167A | c.*1709T>A | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- TYW3 | c.*101T>C | 3'UTR (SNP) | VAF 59/114 reads (52%) | called by muse, mutect2, varscan2
- WNT9A | c.*1159G>A | 3'UTR (SNP) | VAF 21/72 reads (29%) | catalogued as rs979496772; called by muse, mutect2, varscan2
- ZNF41 | c.*572G>A | 3'UTR (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- ZNF654 | c.1035+132C>T | Intron (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
